CPTAC case C3L-00918 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3cbb1a43-04e0-42de-9e40-0aff8356f38e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1947; Vital status: Dead; Days to death: 1,192 days (3.3 years); Year of death: 2020; Cause of death: Cancer Related.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 69.0 years (25,195 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,192 days (3.3 years); Progression or recurrence: yes; Days to last follow up: 1,176 days (3.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm (a second GDC size field records 6.9 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved.

Follow-up (4 entries)
- Days to follow up: 327 days; Disease response: Tumor Free.
- Days to follow up: 700 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,176 days (3.2 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 1,154 days (3.2 years).
- Follow-up contact recording only the day: day 1,061.

Other clinical attributes
- Weight: 113.63 kg; Height: 162.56 cm; BMI: 43.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 22; Cigarettes per day: 20; Tobacco smoking onset year: 1969; Tobacco smoking quit year: 1991; Alcohol history: Yes; Alcohol intensity: Non-Drinker; Exposure duration years: 22.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00918-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 270 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00918-21: Section location: Both posterior and anterior; Percent tumor nuclei: 90; Percent necrosis: 1.
- Sample C3L-00918-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
